Surgical pathology report (de-identified scan), TCGA case TCGA-MT-A67G, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Minnesota, specimen TCGA-MT-A67G-01A (Primary Tumor).

[page 1 of 6]
ID:

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site R Tonsil NOS C09.9
9/5/16/13

SPECIMEN(S):

A: Right tonsil

B: Right parapharyngeal margin

C: Right 2A

D: Right level 3

E: Right 2B

F: Right level 4

FINAL DIAGNOSIS:

A. Tonsil, right, tonsillectomy:

- Squamous cell carcinoma, 2.5 cm, moderately differentiated,
- Deep margin: Positive for carcinoma
- See cancer checklists

B. Parapharyngeal margin, right, excision:

- Salivary glands and fibrovascular tissue, negative for carcinoma

C. Lymph nodes, right 2A, excision:

- Four of seven lymph nodes with metastatic carcinoma (4/7)
- No extranodal extension identified

D. Lymph nodes, right level 3, excision:

- One of thirteen lymph nodes with metastatic carcinoma (1/13)

[page 2 of 6]
- No extranodal extension identified

E. Lymph nodes, right 2B, excision:

- Five lymph nodes, negative for carcinoma (0/5)

F. Lymph nodes, right level 4, excision:

- Twenty three lymph nodes, negative for carcinoma (0/23)

COMMENT:

Specimen: Right tonsil and lymph nodes

Procedure: Tonsillectomy and neck (lymph node) dissection (right 2A, 2B, 3, 4)

Specimen Integrity: Intact

Specimen Size: 4.1 x 4.0 x 2.3: cm

Specimen Laterality: Right

Tumor Site: Tonsil

Tumor Laterality: Right

Tumor Focality: Single focus

Tumor Size: 2.5 x 1.7 x 1.5 cm

Tumor Description: Endophytic

Histologic Type: Squamous cell carcinoma, conventional

Histologic Grade: G2, moderately differentiated

Margins: Posterior margin is involved by invasive carcinoma. The tumor

[page 3 of 6]
is < 0.1 cm from inferior margin.

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Number of Lymph Nodes Examined: 48

Number of Lymph Nodes Involved: 5

Size (greatest dimension) of the largest positive lymph node:

1.1 cm

Extranodal Extension: Absent

Distant Metastasis: Not applicable

Pathologic Staging (pTNM): pT1 N2b Mx

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

The patient is a -year-old female with tonsil cancer. Operative

Procedure: Right radical tonsillectomy with right neck dissection.

GROSS:

Six containers are received, each labeled with the patient's name, and medical record number.

A. The first container is received fresh and subsequently received in

[page 4 of 6]
formalin and additionally labeled "A - right tonsil." The specimen consists of a 4.1 x 4.0 x 2.3 cm radical tonsillectomy specimen. The surgeon was present in the gross room and oriented the specimen. The specimen is also oriented with a stitch at superior aspect. The specimen is inked as follows: superior = orange, inferior = blue, anterior = green, posterior = red and deep = black. A 1.6 x 0.7 cm tan-white, well-defined ulcer is present on the mucosal surface, which is 0.9 cm to the closest inferior margin. Sectioning reveals a 2.5 x 1.7 x 1.5 cm white firm well-defined mass deep to the ulcer within the submucosal tissue. This mass is less than 0.1 cm to deep margin, 0.2 cm to anterior, 0.7 cm to posterior, 1.0 cm to superior and 0.6 cm to inferior margin respectively. Representative sections of the mass were procured for potential future studies. Remainder of tissue is entirely submitted.

Summary of Sections:

A1-A2 - superior margin, perpendicular.

A3-A4 - inferior margin, perpendicular.

A5-A11 - remainder of tissue sequentially proceeding from superior to inferior aspect related to anterior random posterior margins.

B. The next container is additionally labeled "B - right parapharyngeal margin." The specimen consists of four yellow-red fibroadipose tissues measuring ranging from 0.3 to 0.7 cm in greatest dimension and 1.0 x 0.5 x 0.2 cm in aggregate. Entirely wrapped in A1.

[page 5 of 6]
C. The next container is labeled "C - right 2A." The specimen consists of a 4.3 x 3.5 x 1.7 cm portion of yellow-red firm fibroadipose tissue. Sectioning reveals a 3.8 x 3.2 x 2.0 cm white firm mass with solid cut surface. Also two lymph nodes measuring 0.8 and 1.0 cm in greatest dimension are noted. Representative sections are submitted.

Summary of Sections:

C1 - largest firm mass.

C2-C3 - one lymph node in each.

D. The next container is labeled "D - right level 3." The specimen consists of a 4.5 x 2.5 x 0.7 cm portion of yellow-red fibroadipose tissue. Sectioning reveals six lymph nodes ranging from 0.3 to 2.0 cm in greatest dimension. All lymph nodes are entirely submitted.

Summary of Sections:

D1-D3 - one lymph node in each.

D4 - three lymph nodes.

E. The next container is labeled "E - right 2B." The specimen consists of 2.0 x 1.5 x 1.5 cm yellow-white fibroadipose tissue. Sectioning reveals three lymph nodes ranging from 0.5 to 0.7 cm in greatest dimension. The specimen is entirely submitted.

[page 6 of 6]
Summary of Sections:

E1-E3 - one lymph node in each.

F. The next container is labeled "F - right level 4." The specimen consists of a 3.0 x 1.8 x 1.2 cm portion of yellow fibroadipose tissue. Sectioning reveals 14 possible lymph nodes ranging from 0.2 to 0.4 cm in greatest dimension. The entire specimen is submitted.

Summary of Sections:

F1-F2 - four lymph node in each.

F3-F4 - three lymph nodes in each.

F5-F7 - remaining adipose tissue.

MICROSCOPIC:

Microscopic examination is performed.

H&PAA Discrepancy		✓

Source: NCI Genomic Data Commons file 197e2a40-2719-44fc-a91a-4cd00932ee9f (TCGA-MT-A67G.ADA147B3-D9A9-4B9A-AB96-5C0EDE51B735.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).